Somatic mutation profile of tumor specimen C3L-01277-01 (aliquot CPT0093170009) from CPTAC case C3L-01277, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IV; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 61.2 years (22,367 days).
Specimen C3L-01277-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 568c003c-01b8-4084-b6a4-89b349a1dce0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01277-31 (Blood Derived Normal), aliquot CPT0093220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8964acb-a3d8-4a39-a7b3-bd203219fbc2

The open-access MAF lists 73 somatic variants for this specimen: 55 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 13, Nonsense Mutation 3, Frame Shift Del 3, Intron 2, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1699A>G p.K567E (on ENST00000521381 / NM_181523.3; = p.K297E on NM_181504.4) | Missense Mutation (SNP) | VAF 152/321 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57123609; called by muse, mutect2, varscan2
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 158/205 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC191 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as rs754706776; called by muse, mutect2, varscan2
- CCNP | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 299/586 reads (51%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.659); catalogued as rs768712086; called by muse, mutect2, varscan2
- CDH23 | c.2870G>T p.R957L | Missense Mutation (SNP) | VAF 113/303 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.405); catalogued as rs748047907, COSV54954134; called by muse, mutect2, varscan2
- CEP89 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 44/1064 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as rs368927898; called by muse, mutect2
- CFAP94 | c.1212G>T p.M404I (on ENST00000320267 / NM_001352064.2; = p.M410I on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/383 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100208798; called by muse, mutect2, varscan2
- CNPPD1 | c.1128dup p.W377Lfs*50 | Frame Shift Ins (INS) | VAF 79/203 reads (39%) | catalogued as rs764842458; called by mutect2, pindel, varscan2
- CYP11B1 | c.333G>T p.M111I | Missense Mutation (SNP) | VAF 226/594 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as COSV52828863; called by muse, mutect2, varscan2
- ESPL1 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs747148602, COSV57760936, COSV99229212; called by muse, mutect2, varscan2
- FLG | c.11665G>A p.G3889R | Missense Mutation (SNP) | VAF 191/636 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1158578440; called by muse, mutect2, varscan2
- GAPDHS | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 316/554 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55880715; called by muse, varscan2
- GRINA | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as COSV57297431; called by muse, mutect2, varscan2
- GZMB | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs564414889, COSV53543375, COSV53543682; called by muse, mutect2, varscan2
- IRS1 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV59337941; called by muse, mutect2, varscan2
- L1CAM | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 100/465 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62830223; called by muse, mutect2, varscan2
- MAP2K4 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267604739, COSV62256985; called by muse, mutect2, varscan2
- MATN2 | c.1701A>C p.K567N | Missense Mutation (SNP) | VAF 67/456 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.131); catalogued as COSV54709858; called by muse, mutect2, varscan2
- MLYCD | c.1416G>C p.K472N | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.209); catalogued as COSV99076791; called by muse, mutect2, varscan2
- PDE6B | c.2239G>C p.E747Q | Missense Mutation (SNP) | VAF 118/316 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55330446; called by muse, varscan2
- SBSN | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 597/2047 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.214); catalogued as COSV101510115; called by muse, mutect2, varscan2
- SCYL1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 146/383 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs371744623; called by muse, mutect2, varscan2
- SYCP2 | c.3682C>T p.R1228W | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.533); catalogued as rs770144840, COSV62766165; called by muse, mutect2, varscan2
- TIMM8A | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 125/634 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs782391267; called by muse, mutect2, varscan2
- TRPA1 | c.2689C>A p.P897T | Missense Mutation (SNP) | VAF 216/523 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99031131; called by muse, mutect2, varscan2
- TRPA1 | c.2688T>A p.D896E | Missense Mutation (SNP) | VAF 216/526 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as COSV100084672; called by muse, mutect2, varscan2
- TTN | c.48004C>T p.R16002W (on ENST00000591111; = p.R8578W on NM_003319.4) | Missense Mutation (SNP) | VAF 289/639 reads (45%) | PolyPhen probably damaging (0.999); catalogued as rs375944265; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ABCB5 | c.1512T>A p.Y504* (on ENST00000404938 / NM_001163941.2; = p.Y59* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 81/266 reads (30%) | called by muse, mutect2, varscan2
- APAF1 | c.2830A>G p.R944G (on ENST00000551964 / NM_181861.2; = p.R890G on NM_001160.3) | Missense Mutation (SNP) | VAF 98/244 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP35 | c.209_224del p.N70Tfs*96 | Frame Shift Del (DEL) | VAF 126/251 reads (50%) | called by mutect2, pindel, varscan2
- ASCL1 | c.191C>G p.P64R | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- CHD9 | c.2524_2526del p.S842del | In Frame Del (DEL) | VAF 12/127 reads (9%) | called by mutect2, pindel
- CLHC1 | c.269G>T p.R90I | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- CYP11B1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 131/645 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- FOXA2 | c.564G>A p.W188* (on ENST00000377115 / NM_153675.3; = p.W194* on NM_021784.5) | Nonsense Mutation (SNP) | VAF 193/237 reads (81%) | called by muse, mutect2, varscan2
- HMCN1 | c.6779A>T p.E2260V | Missense Mutation (SNP) | VAF 219/348 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KATNIP | c.4565A>T p.D1522V | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LIN37 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 375/1660 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- LIN37 | c.711G>T p.K237N | Missense Mutation (SNP) | VAF 318/1416 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LMBRD1 | c.332G>C p.C111S | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MTARC1 | c.727_728del p.I243Ffs*13 | Frame Shift Del (DEL) | VAF 211/389 reads (54%) | called by mutect2, pindel, varscan2
- NDST4 | c.1685A>T p.E562V | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NLRP7 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPHS1 | c.2785G>C p.D929H | Missense Mutation (SNP) | VAF 418/1609 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PARP8 | c.2372G>A p.C791Y | Missense Mutation (SNP) | VAF 86/178 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- PTPN21 | c.3237A>G p.S1079= | Splice Region (SNP) | VAF 38/75 reads (51%) | called by muse, varscan2
- SBNO1 | c.1100G>T p.G367V (on ENST00000420886; = p.G366V on NM_018183.5) | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SBSN | c.462G>C p.Q154H | Missense Mutation (SNP) | VAF 583/1992 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, varscan2
- SCFD2 | c.1982G>T p.R661L | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- SMC6 | c.768_769del p.R257Ffs*13 | Frame Shift Del (DEL) | VAF 49/178 reads (28%) | called by mutect2, pindel, varscan2
- TTC9B | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 226/463 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ZBTB7B | c.951_968del p.Y317_Q323delins* (on ENST00000292176; = p.Y351_Q357delins* on NM_001252406.3 and 1 other RefSeq transcript) | Nonsense Mutation (DEL) | VAF 73/129 reads (57%) | called by mutect2, pindel, varscan2
- ZNF501 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ZNF573 | c.1317G>T p.M439I (on ENST00000536220 / NM_001172692.1; = p.M381I on NM_152360.3) | Missense Mutation (SNP) | VAF 211/409 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF875 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 428/610 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL9A3 | c.15C>A p.R5= | Silent (SNP) | VAF 35/161 reads (22%) | called by muse, mutect2, varscan2
- GAPDHS | c.876C>T p.V292= | Silent (SNP) | VAF 131/239 reads (55%) | called by muse, mutect2, varscan2
- KCNH6 | c.15G>A p.R5= | Silent (SNP) | VAF 50/225 reads (22%) | catalogued as COSV59007257; called by muse, mutect2, varscan2
- KCNK6 | c.309G>A p.L103= | Silent (SNP) | VAF 294/591 reads (50%) | catalogued as rs1215193238; called by muse, mutect2, varscan2
- NAT10 | c.2964G>A p.L988= | Silent (SNP) | VAF 44/184 reads (24%) | called by muse, mutect2, varscan2
- NEDD9 | c.918C>T p.L306= | Silent (SNP) | VAF 124/367 reads (34%) | catalogued as COSV65219590; called by muse, mutect2, varscan2
- NRG4 | c.45G>A p.S15= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as rs375638068; called by muse, mutect2, varscan2
- RBM42 | c.145C>T p.L49= | Silent (SNP) | VAF 155/308 reads (50%) | called by muse, mutect2, varscan2
- SYTL4 | c.870G>A p.L290= | Silent (SNP) | VAF 51/251 reads (20%) | called by muse, mutect2, varscan2
- TMEM147 | c.243G>A p.L81= | Silent (SNP) | VAF 208/340 reads (61%) | catalogued as COSV52866063, COSV52870579, COSV99382657; called by muse, mutect2, varscan2
- URI1 | c.402G>A p.V134= | Silent (SNP) | VAF 59/211 reads (28%) | called by muse, mutect2, varscan2
- ZNF551 | c.336C>T p.V112= | Silent (SNP) | VAF 140/166 reads (84%) | called by muse, mutect2, varscan2
- ZNF573 | c.1485G>A p.E495= (on ENST00000536220 / NM_001172692.1; = p.E437= on NM_152360.3) | Silent (SNP) | VAF 148/306 reads (48%) | called by muse, mutect2, varscan2
- FBXO16 | c.136-1623G>A | Intron (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- FOXP2 | c.*1550C>G | 3'UTR (SNP) | VAF 111/488 reads (23%) | called by muse, mutect2, varscan2
- NPIPB10P | n.875C>A | RNA (SNP) | VAF 304/1131 reads (27%) | catalogued as rs1457163194; called by muse, varscan2
- PCDHB6 | chr5:141157033 G>A | 3'Flank (SNP) | VAF 97/304 reads (32%) | catalogued as rs979231539; called by muse, mutect2, varscan2
- RTF2 | c.69+1911C>T | Intron (SNP) | VAF 79/237 reads (33%) | called by muse, mutect2, varscan2
